Somatic mutation profile of tumor specimen HCM-SANG-0294-C15-01A (aliquot HCM-SANG-0294-C15-01A-01D-A78U-36) from HCMI case HCM-SANG-0294-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0294-C15-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7003c7ba-8308-4a00-a08d-281771697729.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0294-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0294-C15-10A-01D-A78U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6ef3a49-faad-4e37-b2c0-0a813d52c498

The open-access MAF lists 148 somatic variants for this specimen: 93 protein-altering or splice-affecting, 37 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 37, Intron 6, RNA 5, Frame Shift Ins 3, Nonsense Mutation 3, 5'UTR 3, Splice Site 3, 3'UTR 2, Frame Shift Del 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 130/677 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD30A | c.3192A>C p.E1064D (on ENST00000611781; = p.E1008D on NM_052997.2) | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.806); catalogued as rs1295440874; called by muse, mutect2, varscan2
- AOPEP | c.1849C>T p.H617Y (on ENST00000375315 / NM_001193329.1; = p.H518Y on NM_032823.5) | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52994789; called by muse, mutect2, varscan2
- APOA4 | c.454C>A p.Q152K | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV100759400, COSV63360889; called by muse, mutect2
- BIN1 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 21/262 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs1158338100; called by muse, mutect2
- BTNL2 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 29/272 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.425); catalogued as rs778673342; called by muse, mutect2, varscan2
- CACNA1H | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as rs761025927; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARNS1 | c.1198G>C p.G400R | Missense Mutation (SNP) | VAF 19/344 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs900666958; called by muse, mutect2
- CLCA1 | c.1232C>T p.T411M | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375829347, COSV52324954; called by muse, mutect2, varscan2
- CSPG4 | c.4354G>A p.E1452K | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs774329143; called by muse, mutect2
- DNAJC30 | c.95G>A p.G32D | Missense Mutation (SNP) | VAF 34/403 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs1554611823, COSV104379773; called by muse, mutect2
- ELMO1 | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 103/507 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as rs918674508, COSV60329852; called by muse, mutect2, varscan2
- EPHA5 | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 34/446 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs370503988; called by muse, mutect2
- GALNT17 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 60/380 reads (16%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.017); catalogued as COSV61166417; called by muse, mutect2, varscan2
- GLI3 | c.3040G>A p.E1014K | Missense Mutation (SNP) | VAF 69/449 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs373643864, CM107030; called by muse, mutect2, varscan2
- GOLGA8S | c.1715T>C p.V572A | Missense Mutation (SNP) | VAF 61/346 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV71846641; called by mutect2, varscan2
- GUK1 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 12/283 reads (4%) | catalogued as rs932355338; called by muse, mutect2
- H2AC8 | c.265C>A p.R89S | Missense Mutation (SNP) | VAF 47/615 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV99773431; called by muse, mutect2
- IGHV3-30 | c.150C>G p.S50R | Missense Mutation (SNP) | VAF 76/937 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs375279439; called by muse, mutect2
- IL3RA | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 52/302 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.934); catalogued as rs773005678, COSV58429897; called by muse, mutect2, varscan2
- KCTD19 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 54/550 reads (10%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.446); catalogued as rs749796211, COSV58570995; called by muse, mutect2
- KIAA1109 | c.13213G>C p.V4405L | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.451); catalogued as COSV52667595; called by muse, mutect2
- KLF8 | c.407C>A p.P136H | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV63847479; called by muse, mutect2, varscan2
- LRP1B | c.13304A>G p.K4435R | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV101254879, COSV67186665, COSV67220594; called by muse, mutect2, varscan2
- MAP3K7 | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as rs751058214, COSV65226275; called by muse, mutect2
- MMP11 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 63/472 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200864019; called by muse, mutect2, varscan2
- NPAP1 | c.3213A>T p.Q1071H | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.33); catalogued as rs766197616; called by muse, mutect2
- NTRK2 | c.1946C>A p.T649K (on ENST00000323115 / NM_001369534.1; = p.T665K on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/388 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV52872959; called by muse, mutect2, varscan2
- OBSCN | c.6742G>A p.V2248M | Missense Mutation (SNP) | VAF 20/351 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as rs770438385, COSV52758546; called by muse, mutect2
- OR4C6 | c.190T>G p.L64V | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.216); catalogued as COSV58605224, COSV58606549; called by muse, mutect2, varscan2
- PCDH15 | c.1040T>G p.L347R | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57299220, COSV57350026; called by muse, mutect2
- PCDHA1 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as COSV65373779; called by muse, mutect2, varscan2
- PGAP6 | c.62T>C p.L21P | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1485838519; called by muse, mutect2, varscan2
- PGBD2 | c.814_815del p.M272Vfs*2 | Frame Shift Del (DEL) | VAF 36/330 reads (11%) | catalogued as rs1558289570; called by mutect2, pindel, varscan2
- PITX1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54762031, COSV54763201; called by muse, mutect2
- PLVAP | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 46/327 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.594); catalogued as rs759585750; called by muse, mutect2, varscan2
- POLQ | c.4289dup p.L1430Ffs*5 | Frame Shift Ins (INS) | VAF 14/80 reads (18%) | catalogued as rs755281591, COSV99951761; called by mutect2, varscan2
- RASL11A | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 33/474 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1052031923; called by muse, mutect2
- RGL2 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs151195371; called by muse, mutect2
- RYR1 | c.10901C>T p.A3634V | Missense Mutation (SNP) | VAF 28/702 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62089069; called by muse, mutect2
- SHISAL1 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 47/296 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs376878869; called by muse, mutect2, varscan2
- SLC6A2 | c.1393G>A p.G465R | Missense Mutation (SNP) | VAF 142/561 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1297555256; called by muse, mutect2, varscan2
- SORCS1 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV53908958; called by muse, mutect2
- SPATA5 | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 44/247 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773376572; called by muse, mutect2, varscan2
- SPTA1 | c.2876G>A p.R959Q | Missense Mutation (SNP) | VAF 30/329 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as rs754523316, COSV63750087, COSV63753218; ClinVar: uncertain significance; called by muse, mutect2
- TNFSF14 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 45/354 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs150431195; called by muse, mutect2, varscan2
- TREM2 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 68/557 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs147564421, CM132590; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRHDE | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 21/276 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs1278896797; called by muse, mutect2
- TRIM6 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 32/346 reads (9%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.96); catalogued as rs1214852302, COSV104376274, COSV53478516; called by muse, mutect2
- ZNF511 | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 16/346 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1259773746; called by muse, mutect2
- ZNF843 | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.324); catalogued as COSV59847690; called by muse, mutect2, varscan2
- ANKRD30A | c.4189T>C p.S1397P (on ENST00000611781; = p.S1341P on NM_052997.2) | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- ARID1A | c.6494_6495insCATG p.E2165Dfs*61 | Frame Shift Ins (INS) | VAF 74/291 reads (25%) | called by mutect2, varscan2
- ARID1A | c.6499_6502dup p.V2168Gfs*58 | Frame Shift Ins (INS) | VAF 71/289 reads (25%) | called by mutect2*, pindel, varscan2*
- ASTN1 | c.823C>G p.L275V | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CCDC82 | c.765_786+15del p.X255_splice | Splice Site (DEL) | VAF 16/124 reads (13%) | called by mutect2, pindel
- CDRT1 | c.1595G>C p.R532T | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- CFAP46 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 12/289 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); called by muse, mutect2
- GLI3 | c.4116C>A p.S1372R | Missense Mutation (SNP) | VAF 40/1016 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); called by muse, mutect2
- GON4L | c.4662G>C p.E1554D | Missense Mutation (SNP) | VAF 21/349 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.534); called by muse, mutect2
- HORMAD1 | c.185G>T p.C62F | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- HTR1B | c.805T>A p.S269T | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.254); called by muse, mutect2
- HUWE1 | c.4897A>C p.S1633R | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.813); called by muse, mutect2
- IGHV1OR15-9 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 32/362 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.145); called by muse, mutect2
- IMPG1 | c.1616A>G p.Y539C | Missense Mutation (SNP) | VAF 16/217 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); called by muse, mutect2
- KRT84 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 56/343 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KRTAP27-1 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LCN2 | c.245A>T p.K82M | Missense Mutation (SNP) | VAF 38/460 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); called by muse, mutect2
- MKRN3 | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 26/283 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- NLRP10 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 31/418 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.242); called by muse, mutect2
- NPR3 | c.1424C>A p.S475* | Nonsense Mutation (SNP) | VAF 16/170 reads (9%) | called by muse, mutect2
- NRG1 | c.986A>C p.E329A (on ENST00000405005 / NM_013964.5; = p.E334A on NM_013956.5) | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- PABPC5 | c.775T>A p.L259M | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- PCDH15 | c.4435C>A p.Q1479K | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- PCDH15 | c.2881A>G p.S961G | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.131); called by muse, mutect2
- PHB2 | c.712-2A>G p.X238_splice | Splice Site (SNP) | VAF 12/169 reads (7%) | called by muse, mutect2
- PRH2 | c.111C>G p.D37E | Missense Mutation (SNP) | VAF 56/422 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- QSOX1 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 16/199 reads (8%) | called by muse, mutect2
- SNTG2 | c.259A>G p.S87G | Missense Mutation (SNP) | VAF 47/265 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SOX30 | c.1516C>G p.P506A | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.268); called by muse, mutect2
- SPATS1 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 27/257 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- TBC1D19 | c.447C>G p.F149L | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TIGD4 | c.652G>T p.V218F | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TNN | c.3040G>A p.V1014I | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TPO | c.1697T>C p.V566A | Missense Mutation (SNP) | VAF 28/479 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.097); called by muse, mutect2
- TRAPPC3L | c.326A>G p.K109R | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.516); called by muse, mutect2
- TRIL | c.1903C>G p.R635G | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1828A>C p.M610L | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TRIM64C | c.216G>T p.K72N | Missense Mutation (SNP) | VAF 78/693 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TTLL5 | c.2382_2387+10del p.X794_splice | Splice Site (DEL) | VAF 8/92 reads (9%) | called by mutect2, pindel
- USP17L1 | c.988T>C p.C330R | Missense Mutation (SNP) | VAF 48/361 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- VAT1L | c.1144A>G p.K382E | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.036); called by muse, mutect2
- XKR5 | c.1174C>A p.Q392K | Missense Mutation (SNP) | VAF 17/427 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.85); called by muse, mutect2
- ANAPC1 | c.2469T>C p.I823= | Silent (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2, varscan2
- ATP10A | c.1431G>A p.S477= | Silent (SNP) | VAF 25/508 reads (5%) | catalogued as rs377377929; called by muse, mutect2
- BRPF1 | c.3591G>A p.Q1197= | Silent (SNP) | VAF 14/245 reads (6%) | catalogued as COSV57353523; called by muse, mutect2
- CNTN1 | c.2955A>G p.G985= | Silent (SNP) | VAF 27/331 reads (8%) | called by muse, mutect2
- EXTL3 | c.2256C>T p.D752= | Silent (SNP) | VAF 32/475 reads (7%) | catalogued as rs781276373, COSV55037022; called by muse, mutect2
- FAM217A | c.555T>C p.N185= | Silent (SNP) | VAF 29/227 reads (13%) | catalogued as rs756907917; called by muse, mutect2, varscan2
- FAM83C | c.156C>T p.L52= | Silent (SNP) | VAF 145/728 reads (20%) | called by muse, mutect2, varscan2
- FCAMR | c.657C>T p.P219= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs552971213; called by muse, mutect2
- FER1L6 | c.3444C>T p.D1148= | Silent (SNP) | VAF 19/187 reads (10%) | called by muse, mutect2
- FIGN | c.2196T>G p.A732= | Silent (SNP) | VAF 35/236 reads (15%) | called by muse, mutect2, varscan2
- FLNC | c.4395C>T p.F1465= | Silent (SNP) | VAF 42/303 reads (14%) | called by muse, mutect2, varscan2
- GDPGP1 | c.225G>C p.L75= | Silent (SNP) | VAF 44/419 reads (11%) | called by muse, mutect2, varscan2
- HEATR1 | c.2529T>C p.V843= | Silent (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- HIC1 | c.492C>T p.G164= (on ENST00000322941 / NM_001098202.1; = p.G145= on NM_006497.4) | Silent (SNP) | VAF 22/224 reads (10%) | called by muse, mutect2
- HMCN1 | c.14052A>C p.G4684= | Silent (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- HYDIN | c.7593G>A p.A2531= | Silent (SNP) | VAF 38/243 reads (16%) | catalogued as rs185945967, COSV59253502; called by muse, mutect2, varscan2
- IL31 | c.78G>A p.T26= | Silent (SNP) | VAF 23/250 reads (9%) | catalogued as rs557327465; called by muse, mutect2
- KATNIP | c.4431T>C p.A1477= | Silent (SNP) | VAF 57/322 reads (18%) | called by muse, mutect2, varscan2
- KMT2D | c.14673G>A p.Q4891= | Silent (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2
- LDOC1 | c.399C>T p.D133= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as COSV100983140; called by muse, mutect2
- MYBPC3 | c.1545C>T p.N515= | Silent (SNP) | VAF 15/217 reads (7%) | catalogued as rs771230605, CD115914, COSV57029249; called by muse, mutect2
- NCOR2 | c.6630G>T p.S2210= | Silent (SNP) | VAF 31/138 reads (22%) | called by muse, mutect2, varscan2
- PCDHA11 | c.648C>T p.D216= | Silent (SNP) | VAF 14/215 reads (7%) | catalogued as rs1562632987; called by muse, mutect2
- QSER1 | c.2304T>G p.L768= (on ENST00000399302; = p.L897= on NM_001076786.3) | Silent (SNP) | VAF 12/200 reads (6%) | called by muse, mutect2
- RIMS1 | c.211A>C p.R71= | Silent (SNP) | VAF 40/470 reads (9%) | catalogued as rs980106766, COSV53441304, COSV53444045, COSV53451865; called by muse, mutect2
- RPRD2 | c.3723G>A p.S1241= | Silent (SNP) | VAF 22/242 reads (9%) | catalogued as rs374095080; called by muse, mutect2
- SLC8A1 | c.2466T>G p.A822= | Silent (SNP) | VAF 30/262 reads (11%) | called by muse, mutect2, varscan2
- SMG6 | c.2238G>A p.A746= | Silent (SNP) | VAF 17/260 reads (7%) | catalogued as rs147760228, COSV53966407; called by muse, mutect2
- SMO | c.198G>A p.R66= | Silent (SNP) | VAF 38/390 reads (10%) | called by muse, mutect2
- SORCS1 | c.21C>T p.G7= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- SRRT | c.234G>A p.K78= | Silent (SNP) | VAF 16/152 reads (11%) | called by muse, mutect2
- ST8SIA2 | c.1053G>A p.E351= | Silent (SNP) | VAF 16/300 reads (5%) | called by muse, mutect2
- TMTC1 | c.1179G>A p.P393= (on ENST00000539277 / NM_001193451.2; = p.P285= on NM_175861.3) | Silent (SNP) | VAF 42/307 reads (14%) | catalogued as rs372059579; called by muse, mutect2, varscan2
- TNC | c.1119C>T p.S373= | Silent (SNP) | VAF 58/294 reads (20%) | catalogued as rs746230579, COSV60784001; called by muse, mutect2, varscan2
- TP53BP2 | c.885G>A p.E295= (on ENST00000343537 / NM_001031685.3; = p.E166= on NM_005426.2) | Silent (SNP) | VAF 26/253 reads (10%) | called by muse, mutect2
- ZMIZ2 | c.1395G>A p.L465= | Silent (SNP) | VAF 36/347 reads (10%) | called by muse, mutect2
- ZNF229 | c.1800C>T p.Y600= | Silent (SNP) | VAF 26/232 reads (11%) | catalogued as rs536903685, COSV52161480; called by muse, mutect2, varscan2
- AC079612.1 | n.190A>T | RNA (SNP) | VAF 77/404 reads (19%) | called by muse, mutect2, varscan2
- AC114741.1 | n.229G>T | RNA (SNP) | VAF 7/130 reads (5%) | called by muse, mutect2
- AP4B1 | c.1199-27G>A | Intron (SNP) | VAF 34/284 reads (12%) | catalogued as rs751648698; called by mutect2, varscan2
- ARMCX4 | c.1039-4412A>T | Intron (SNP) | VAF 24/205 reads (12%) | called by muse, mutect2, varscan2
- BID | chr22:17774443 A>C | 5'Flank (SNP) | VAF 48/262 reads (18%) | called by muse, mutect2, varscan2
- C6orf118 | c.*1C>T | 3'UTR (SNP) | VAF 13/129 reads (10%) | catalogued as rs780395167, COSV100024772; called by muse, mutect2
- DCHS2 | n.1141A>C | RNA (SNP) | VAF 18/315 reads (6%) | called by muse, mutect2
- FMN1 | c.2044-2679A>G | Intron (SNP) | VAF 13/356 reads (4%) | called by muse, mutect2
- G6PC3 | c.*198C>A | 3'UTR (SNP) | VAF 79/367 reads (22%) | called by muse, mutect2, varscan2
- HLA-F | chr6:29726976 G>A | 3'Flank (SNP) | VAF 69/478 reads (14%) | catalogued as rs372820182, COSV99466511; called by muse, mutect2, varscan2
- HMGB1P1 | n.70C>T | RNA (SNP) | VAF 32/384 reads (8%) | catalogued as rs758693908; called by muse, mutect2
- LPAL2 | n.384C>T | RNA (SNP) | VAF 8/123 reads (7%) | called by muse, mutect2
- PCDH9 | c.3036+13T>A | Intron (SNP) | VAF 19/145 reads (13%) | called by muse, mutect2, varscan2
- PPFIA4 | c.-304G>C | 5'UTR (SNP) | VAF 54/233 reads (23%) | called by muse, mutect2, varscan2
- PTPRN | c.115+257C>T | Intron (SNP) | VAF 31/384 reads (8%) | catalogued as rs772928537; called by muse, mutect2
- SPATA31C1 | n.523-153A>G | Intron (SNP) | VAF 68/414 reads (16%) | called by mutect2, varscan2
- THBD | c.-39C>T | 5'UTR (SNP) | VAF 35/250 reads (14%) | called by muse, mutect2, varscan2
- ZNF132 | c.-60T>A | 5'UTR (SNP) | VAF 17/230 reads (7%) | called by muse, mutect2
